Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4992, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4992-01A (Primary Tumor).

[page 1 of 3]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4992

Clinical Diagnosis & History:

with left renal mass.

Specimens Submitted:

1: SP: Kidney, left, total nephrectomy

2: SP: Fat, left, perinephric, upper pole, excision

DIAGNOSIS:

1. SP: Kidney, left, total nephrectomy):

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with focal (<5%) sarcomatoid features

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 5.6 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion also not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Two papillary adenomas, benign cortical cysts and mild arteriosclerotic changes

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: Fat, left, perinephric, upper pole, excision (am);

Benign fibroadipose tissue

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh for frozen section, labeled "left radical nephrectomy" and consists of three fragments of a total nephrectomy specimen with attached ureter, renal vessels and perinephric fat weighing 641 g in total. The kidney fragments measures 8.0 to 10.0 cm a greatest dimension. The attached ureter measures 0.4 cm in diameter. The attached renal vein measures 0.2 cm in length and 0.5 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. No adrenal gland is identified on the specimen. The external surface of the specimen is inked black. Sectioning of the kidney fragments reveals a 5.6 x 4.0 x 3.5 cm tumor in the mid portion of the kidney. Sectioning through the tumor reveals a light tan to orange to maroon soft, variegated cut surface. Grossly, the tumor appears to extend to the perirenal adipose tissue. The renal capsule is noticeable for a 3.5 x 3.0 cm retention cyst which is filled with clear fluid. Sections through the remainder of the kidney reveal a pink-brown parenchyma, with a well-defined cortico-medullary junction. The renal pelvis is not identifiable. The cortex measures 0.7 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
K -- representative sections kidney
C -- renal cortical cyst
FSCA -- frozen section control A
FSCB -- frozen section control B

2). The specimen is received fresh, labeled "upper pole perinephric left" and consist of a 14.0 x 13.0 x 9.0 cm segment of fibroadipose tissue. The specimen is early sections reveal no gross abnormality. Representative sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Kidney, left, total nephrectomy

Block	Sect. Site	PCs
1	C	1
1	FSCA	1
1	FSCB	1
2	K	2
3	T	3
4	THF	4

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

2	TK	2
1	TSF	1
1	UVM	1

Part 2: SP: Fat, left, perinephric, upper pole, excision [REDACTED]

Block	Sect. Site	PCs
2	U	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA; ON REPRESENTATIVE SECTION. FINAL CLASSIFICATION PENDING PERMANENT SECTIONS. [REDACTED]
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file d72c61e8-5d87-4a25-97b6-53981e5e751e (TCGA-BP-4992.FAE1E9CE-EEA7-4278-8519-21225010F1F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).